Surgical pathology report (de-identified scan), TCGA case TCGA-98-A53J, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A53J-01A (Primary Tumor).

[page 1 of 3]
1CB-0-3
carcinoma, squamous cell, NOS 807013
Site: lung, (R) upper lobe C34.1 W 11/25/12

Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY CASE:

Diagnosis

- A: Pleura, right, excision: - Negative for malignancy.
- B: Lymph node, level 7, excision: - Multiple lymph node fragments, all negative for malignancy.
- C: Lymph node, level 7, excision: - Negative for malignancy.
- D: Lymph node, level 9, excision: - Negative for malignancy.
- E: Lymph node, level 8, excision: - Negative for malignancy.
- F: Lymph node, level 8, excision: - Negative for malignancy.
- G: Lymph node, level 11, excision: - Multiple lymph node fragments all negative for malignancy.
- H: Lymph node, 10R, excision: - Fibrosis and anthracosis. - No nodal tissue identified.
- I: Lung, bronchial margin, excision: - Negative for malignancy.
- J: Lung, right upper lobe, excision: - Squamous cell carcinoma, moderately differentiated. - The tumor measures 4.9 cm in maximum dimension. - Pleura uninvolved by neoplasm. - Stapled margins negative for malignancy. - Six parabronchial lymph nodes all negative for malignancy (0/6). Lymphovascular invasion is not identified.
- K: Lymph node, level 4, excision: - Multiple lymph node fragments all negative for malignancy.
- L: Lymph node, level 2, excision: - Negative for malignancy.

Clinical Information

The patient is a year old male with a history of hemoptysis, right upper lobe mass, calcified lymph nodes.

Frozen Section Diagnosis

- H1: Lymph node, 10-R, biopsy: - No lymphoid tissue. - Fibrosis.
- I1: Lung, right upper lobe, bronchial margin, excision: - No tumor seen.
- J1: Lung, right upper lobe, excision: - Squamous carcinoma.

Gross Description

The specimen is received in 12 containers labeled with the patient's name and medical record number. Specimen 1 is received in a container of formalin labeled with the patient's name and medical record number and "#1-pleura- right." The specimen consist of a fragment of yellow-tan, fibroadipose tissue measuring 2.7 x 1.6 x 0.4 cm. The specimen is entirely submitted in cassette A1.

Specimen 2 is received in a container of formalin labeled with the patient's name and medical record number and "#2-level VII lymph node." The specimen consist of a pink-tan fragment of lymphoid tissue measuring 2.5 x 1.4 x 0.7 cm. The specimen is sectioned and submitted entirely in cassette B1.

[page 2 of 3]
Specimen 3 is received in a container of formalin labeled with the patient's name and medical record number and "#3-level VII lymph node." The specimen consist of a fragment of pink-tan lymphoid tissue measuring 2.3 x 1.3 x 0.6 cm. The specimen is sectioned and submitted entirely in cassette C1.

Specimen 4 is received in a container of formalin labeled with the patient's name, medical record number and "#4-level IX lymph node." The specimen consist of a fragment of tan, lymphoid tissue measuring 0.6 x 0.5 x 0.3 cm. The specimen is submitted entirely in cassette D1.

Specimen 5 is received in a container of formalin labeled with the patient's name, medical record number and "#5-level VIII lymph node." The specimen consist of a fragment of pink-tan lymphoid tissue measuring 1.2 x 0.6 x 0.4 cm. The specimen is submitted entirely in cassette E1.

Specimen 6 is received in a container of formalin labeled with the patient's name, medical record number and "#6-level VIII lymph node." The specimen consist of a fragment of yellow-tan, lymphoid and adipose tissue measuring 1.1 x 0.5 x 0.2 cm. The specimen is submitted entirely in cassette F1.

Specimen 7 is received in a container of formalin labeled with the patient's name, medical record number and "#7-level XI lymph node." The specimen consist of multiple fragments of pink and brown lymphoid tissue measuring 2.1 x 1.3 x 0.6 cm in aggregate. The specimen is entirely submitted in cassette G1.

Specimen 8 is received in a container of formalin labeled with the patient's name, medical record number and "#8-10 R lymph node-frozen". The specimen consist of an orange cassette labeled, A1-green H that contains a fragment of brown-tan, soft tissue measuring 0.8 x 0.5 x 0.2 cm. The specimen is entirely submitted in cassette H1.

Specimen 9 is received in a container of formalin labeled with the patient's name, medical record number and "#9-right bronchial margin-frozen." The specimen consist of an orange cassette labeled, "I1" that contains fragments of yellow-tan, soft tissue measuring 1.1 x 1.0 x 0.2 cm. The specimen is entirely submitted in cassette I1.

Specimen 10 is received in a container of formalin labeled with the patient's name, medical record number and "#10-right upper lobe." The specimen consist of an orange cassette labeled J1 that contains a fragment of yellow-tan soft tissue measuring 2.3 x 1.5 x 0.3 cm. The specimen is resubmitted as permanent section J1. The remainder of the specimen consists of a lobe of lung measuring 13.5 x 11.4 x 5.8 cm that has already been opened to reveal a tan-brown tumor mass measuring 4.9 x 3.5 x 4.2 cm. The pleura overlying the tumor is thickened with areas of retraction. Tissue from the bronchial region is submitted in cassette J2. Shaved parenchymal stapled margin is submitted in cassettes J3 and J4. Sections of tumor in relation of pleura is submitted in cassettes J5-J6. Additional sections of tumor is submitted in cassettes J7-J9. The tumor is white-tan, yellow with areas of necrosis. Sectioning through the remainder of the lung reveals no additional lesions, there is some pleural fibrosis and thickening near the apex of the lung. Representative section is submitted in cassette J10. Representative uninvolved parenchyma is submitted in cassette J11. Fragments of peribronchial lymph nodes are submitted in cassette J12. The tumor is located approximately 1.1 cm from the bronchial margin and 1.8 cm from the closest stapled margin.

Specimen 11 is received in a container of formalin labeled with the patient's name, medical record number and "#11-level IV lymph node." The specimen consist of multiple fragments of pink-tan lymphoid and yellow, adipose tissue measuring 3.1 x 2.2 x 0.7 cm in aggregate. The specimen is sectioned and entirely submitted in cassettes K1-K2.

Specimen 12 is received in a container of formalin labeled with the patient's name, medical record number and "#12-level II lymph node." The specimen consist of a fragment of pink lymphoid and yellow, adipose tissue measuring 1.6 x 1.2 x 0.6 cm. The specimen is sectioned and entirely submitted in cassette L1.

Block Summary

- A1- Pleura-right.
- B1- Level VII lymph node.
- C1- Level VII lymph node.
- D1- Level IX lymph node.
- E1- Level VIII lymph node.
- F1- Level VIII lymph node.
- G1- Level XI lymph node.
- H1- 10R lymph node.
- I1- Right bronchial margin.
- J1- Right upper lobe, bronchial margin.
- J2- Right upper lobe, tissue from bronchial region.
- J3-J4- Parenchymal shave margin.

[page 3 of 3]
J5-J6- Tumor in relation of pleura.
J7-J9- Representative sections of tumor.
J10- Region of thickened pleura.
J11- Uninvolved parenchyma.
J12- Fragments of bronchial lymph nodes.
K1-K2- Level IV lymph node.
L1- Level II lymph node.

Microscopic Description

A microscopic examination has been performed.

SP Synoptic Report

SPECIMEN: Lobe(s) of lung: RUL

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Upper lobe

TUMOR SIZE: Greatest dimension: 4.9 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION: Not identified

BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

VASCULAR MARGIN: Uninvolved by invasive carcinoma

PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

CHEST WALL MARGIN: Not applicable

LYMPH-VASCULAR INVASION: Not identified

PRIMARY TUMOR (pT): pT2a: Tumor > 3 cm, and < 5 cm in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion in the main bronchus; or Tumor < 5 cm in greatest dimension with any of the following: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM): Not applicable

Crit-#	Yes	No
Metastasis Discrepancy		✓

Source: NCI Genomic Data Commons file cddf9145-84c5-4c24-ae25-a811f5eaa12c (TCGA-98-A53J.DFE3709F-1806-4D6E-8E4A-F33BEE0BABFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).